Somatic mutation profile of tumor specimen TCGA-MI-A75C-01A (aliquot TCGA-MI-A75C-01A-11D-A32G-10) from TCGA case TCGA-MI-A75C, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 64.2 years (23,441 days).
Specimen TCGA-MI-A75C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a378f4c-e50e-4973-80c4-8af73c977a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MI-A75C-10A (Blood Derived Normal), aliquot TCGA-MI-A75C-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e9b413a-6180-4bbe-8f7d-bbf2f363b376

The open-access MAF lists 133 somatic variants for this specimen: 99 protein-altering or splice-affecting, 27 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 27, Frame Shift Del 7, Nonsense Mutation 6, Intron 4, Splice Site 3, 5'UTR 2, Splice Region 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 71/154 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACR | c.835T>C p.W279R | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV53360429; called by muse, mutect2, varscan2
- ADAM12 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64103069; called by muse, mutect2, varscan2
- ALX1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV57491310; called by muse, mutect2, varscan2
- ANPEP | c.2337G>A p.W779* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV55589453; called by muse, mutect2
- ANPEP | c.2335T>G p.W779G | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55589462; called by muse, mutect2
- ARFRP1 | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.152); catalogued as rs774605679, COSV60831173; called by muse, mutect2, varscan2
- ATRN | c.1417T>G p.Y473D | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53524298; called by muse, mutect2, varscan2
- BCL9L | c.4417C>A p.P1473T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV52682262; called by muse, mutect2, varscan2
- BDKRB2 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs769027698, COSV60013752; called by muse, mutect2, varscan2
- C6orf226 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV59034248; called by muse, mutect2, varscan2
- CARS2 | c.632T>G p.V211G | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57284226, COSV99959807; called by muse, mutect2, varscan2
- CC2D1B | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52558908; called by muse, mutect2, varscan2
- CCDC88C | c.2404G>C p.D802H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV66234549; called by muse, mutect2, varscan2
- CCSER1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.636); catalogued as COSV61410744, COSV61431426; called by muse, mutect2, varscan2
- CD164L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV64995498; called by muse, mutect2, varscan2
- CD22 | c.1964G>C p.G655A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50049765; called by muse, mutect2, varscan2
- CELSR2 | c.7231A>G p.I2411V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs78104849, COSV54767451; called by muse, mutect2, varscan2
- CFAP74 | c.1807G>C p.G603R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753826897, COSV54564976, COSV54568040; called by muse, mutect2, varscan2
- CHD1L | c.1539G>A p.Q513= | Splice Region (SNP) | VAF 21/62 reads (34%) | catalogued as COSV63612902; called by muse, mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as rs749719822, COSV99752279; called by pindel, varscan2
- COPZ1 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50431975; called by muse, mutect2, varscan2
- CPT1B | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs148070553; called by muse, mutect2, varscan2
- CSMD3 | c.8693C>A p.T2898K (on ENST00000297405 / NM_001363185.1; = p.T2729K on NM_052900.3) | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.309); catalogued as rs1443134686, COSV52111551; called by muse, mutect2, varscan2
- CYP11B2 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV59994576; called by muse, mutect2, varscan2
- DICER1 | c.2378A>G p.Y793C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs527568726, COSV58616085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYSL2 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV60782185; called by muse, mutect2, varscan2
- DSCAML1 | c.2627G>A p.R876Q (on ENST00000321322; = p.R816Q on NM_020693.4) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); catalogued as rs1028890107, COSV58382762; called by muse, mutect2, varscan2
- DSEL | c.2734G>T p.D912Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59489640; called by muse, mutect2, varscan2
- EPB41L4A | c.555-1G>A p.X185_splice | Splice Site (SNP) | VAF 19/59 reads (32%) | catalogued as rs779283453, COSV54863282, COSV99813322; called by muse, mutect2, varscan2
- EPHA8 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758018689, COSV51263200; called by muse, mutect2, varscan2
- FAM124B | c.484A>T p.R162* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV66271334; called by muse, mutect2, varscan2
- FHOD3 | c.710C>A p.T237K | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.383); catalogued as COSV57165633; called by muse, mutect2, varscan2
- FMO2 | c.1351T>A p.S451T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.272); catalogued as COSV52946857; called by muse, mutect2, varscan2
- FZD5 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV54942967; called by muse, mutect2, varscan2
- GABRA6 | c.97A>G p.S33G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV50877852, COSV99194586; called by muse, mutect2, varscan2
- GALK1 | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as rs925336919, COSV56689512; called by muse, mutect2, varscan2
- GPR174 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52131604; called by muse, mutect2, varscan2
- HGS | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as COSV100230761; called by muse, mutect2, varscan2
- HGS | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100230764; called by muse, mutect2, varscan2
- HIVEP1 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV65099050; called by muse, mutect2, varscan2
- HNF4G | c.914A>T p.Q305L (on ENST00000354370 / NM_001330561.2; = p.Q352L on NM_004133.5) | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV62966055; called by muse, mutect2, varscan2
- KHDC4 | c.1065T>G p.Y355* | Nonsense Mutation (SNP) | VAF 192/227 reads (85%) | catalogued as COSV64164596; called by muse, mutect2, varscan2
- KRT10 | c.1079G>C p.S360T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.349); catalogued as COSV54088432; called by muse, mutect2, varscan2
- LRP4 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV66134199; called by muse, mutect2, varscan2
- MRC2 | c.226C>A p.R76S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs748134416, COSV57637065, COSV57639770; called by muse, mutect2, varscan2
- MUC16 | c.7268A>C p.N2423T | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV67447714; called by muse, mutect2
- N4BP2L2 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs375163250; called by muse, mutect2, varscan2
- NEO1 | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV56067973; called by muse, mutect2, varscan2
- OR13C9 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52240800; called by muse, mutect2, varscan2
- OR2M3 | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV71758887; called by muse, mutect2, varscan2
- PCARE | c.1669G>T p.V557L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59053256; called by muse, mutect2, varscan2
- PCYT1A | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs938675798, COSV53056188; called by muse, mutect2, varscan2
- PHRF1 | c.3542G>T p.R1181L (on ENST00000264555 / NM_001286581.2; = p.R1180L on NM_020901.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs761451455, COSV52751616; called by muse, mutect2, varscan2
- PI4K2A | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.264); catalogued as rs989406282, COSV65701020; called by muse, mutect2, varscan2
- PIGL | c.462C>A p.H154Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56683964; called by muse, mutect2, varscan2
- PKD1 | c.6544C>G p.Q2182E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV51911389; called by muse, mutect2, varscan2
- PKMYT1 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs1393471434, COSV51890921; called by muse, mutect2, varscan2
- REV1 | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51482134; called by muse, mutect2, varscan2
- RGS12 | c.2134T>A p.W712R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58749094; called by muse, mutect2
- RIPK3 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV53474367; called by muse, mutect2, varscan2
- ROCK1 | c.1799A>C p.D600A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV67694654; called by muse, mutect2, varscan2
- SESN2 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV53426759; called by muse, mutect2, varscan2
- SFRP2 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56836887; called by muse, mutect2, varscan2
- SLC12A2 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV52468710; called by muse, mutect2, varscan2
- SNRPN | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); catalogued as COSV57594364, COSV57599888; called by muse, mutect2, varscan2
- SRGAP3 | c.775A>C p.I259L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.127); catalogued as COSV64530866; called by muse, mutect2, varscan2
- STOX2 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1246197618, COSV57849084; called by muse, mutect2, varscan2
- TAL2 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs573416391, COSV61883655; called by muse, mutect2, varscan2
- TBPL2 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55955623; called by muse, mutect2, varscan2
- TIAM2 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV59690099; called by muse, mutect2, varscan2
- TNFRSF4 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV55417787; called by muse, mutect2, varscan2
- TNIP1 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV59304042; called by muse, mutect2, varscan2
- TOGARAM2 | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV65420000; called by muse, mutect2, varscan2
- TONSL | c.2970G>C p.Q990H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV101340228, COSV68047720; called by muse, mutect2, varscan2
- TOPORS | c.887T>C p.L296S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1388317247, COSV62116253; called by muse, mutect2, varscan2
- TPO | c.699G>A p.W233* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100220555, COSV61095955; called by muse, mutect2, varscan2
- TRAK2 | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.047); catalogued as rs1559438421, COSV60270488; called by muse, mutect2, varscan2
- TSKU | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60750905; called by muse, varscan2
- USP9X | c.1216C>G p.Q406E | Missense Mutation (SNP) | VAF 124/171 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100198573, COSV61066468; called by muse, mutect2, varscan2
- VCAN | c.1966T>C p.F656L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as COSV54097893; called by muse, mutect2, varscan2
- ZC3H7A | c.1648A>T p.N550Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.342); catalogued as COSV63268664; called by muse, mutect2, varscan2
- ZFYVE26 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as rs766869217, COSV61324893; called by muse, mutect2, varscan2
- ZNF217 | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56594300; called by muse, mutect2, varscan2
- ZNF415 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV54699294; called by muse, mutect2, varscan2
- ZNF695 | c.1261T>C p.S421P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60584815; called by muse, mutect2, varscan2
- ZNF831 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV64037790; called by muse, mutect2, varscan2
- ARID2 | c.170del p.L57* | Frame Shift Del (DEL) | VAF 42/115 reads (37%) | called by mutect2, pindel, varscan2
- ARID2 | c.4595del p.N1532Ifs*3 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- CBFA2T2 | c.391_399dup p.N131_I133dup | In Frame Ins (INS) | VAF 18/70 reads (26%) | called by mutect2, varscan2
- CHD4 | c.2121_2133del p.D707Efs*11 (on ENST00000357008 / NM_001363606.2; = p.D720Efs*11 on NM_001273.5) | Frame Shift Del (DEL) | VAF 43/113 reads (38%) | called by mutect2, pindel, varscan2
- DTX3L | c.1565A>T p.E522V | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- FXR2 | c.1908_1926+11del p.X636_splice | Splice Site (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel
- IGHA1 | c.641C>G p.P214R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- KCNC3 | c.284del p.G95Afs*23 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- MDC1 | c.366_367del p.F123Cfs*2 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by pindel, varscan2
- PRKACB | c.546+3_546+4dup p.X182_splice | Splice Site (INS) | VAF 47/131 reads (36%) | called by mutect2, pindel, varscan2
- SHOX | c.293_294del p.K98Rfs*83 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- AMPD3 | c.2286C>T p.I762= (on ENST00000396553 / NM_001025389.2; = p.I771= on NM_000480.3) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs766657663, COSV67330019; called by muse, mutect2, varscan2
- ANXA1 | c.816A>T p.T272= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV57410508; called by muse, mutect2
- CHRNA3 | c.639A>T p.P213= | Silent (SNP) | VAF 4/92 reads (4%) | catalogued as COSV58774188; called by muse, mutect2
- COL13A1 | c.1410G>T p.G470= (on ENST00000398978 / NM_001130103.2; = p.G413= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV62567382; called by muse, mutect2, varscan2
- DISP3 | c.3318C>T p.H1106= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs749918646, COSV53821290; called by muse, mutect2, varscan2
- DNAH7 | c.1092T>A p.A364= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV56753585; called by muse, mutect2, varscan2
- EEA1 | c.2109T>C p.H703= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as rs1401314944, COSV59282952; called by muse, mutect2, varscan2
- ESRRB | c.9G>A p.S3= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs755277884, COSV55059036; called by muse, mutect2, varscan2
- EZHIP | c.1170T>A p.P390= | Silent (SNP) | VAF 57/71 reads (80%) | catalogued as COSV100539910; called by muse, mutect2, varscan2
- FADD | c.51C>T p.S17= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1441791156, COSV57228936; called by muse, mutect2, varscan2
- FLG2 | c.6426G>T p.G2142= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV66166883, COSV66172232; called by muse, mutect2, varscan2
- GLCE | c.1008T>C p.D336= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs1307137757, COSV55944447; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.94C>T p.L32= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV59822646; called by muse, mutect2, varscan2
- LAMB1 | c.3408C>T p.P1136= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs971343938, COSV55961990, COSV55971285; called by muse, mutect2
- OR2L13 | c.546C>T p.A182= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as COSV63548745; called by muse, mutect2, varscan2
- OR5D18 | c.537C>T p.F179= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV61736345; called by muse, mutect2, varscan2
- PLEKHA5 | c.1449A>G p.T483= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs376638119; called by muse, mutect2, varscan2
- PTPRB | c.3882G>A p.E1294= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as COSV54233526; called by muse, mutect2, varscan2
- RASAL3 | c.726C>A p.A242= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV59138461, COSV59141867; called by muse, mutect2, varscan2
- RP1 | c.423C>T p.P141= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs766819017, COSV55110928; called by muse, mutect2, varscan2
- SAR1B | c.333A>T p.S111= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV68391318; called by muse, mutect2, varscan2
- SEC16A | c.585G>T p.V195= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV51522045; called by muse, mutect2, varscan2
- SOX30 | c.1884A>G p.T628= (on ENST00000265007 / NM_178424.2; = p.H464R on NM_007017.2) | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV53936255; called by muse, mutect2, varscan2
- SRSF12 | c.24C>T p.P8= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV101504995, COSV71683625; called by muse, varscan2
- STMN4 | c.57C>T p.F19= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV56108308; called by muse, mutect2, varscan2
- USP40 | c.1443A>G p.K481= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV52477704; called by muse, mutect2, varscan2
- XIRP2 | c.4506C>T p.I1502= (on ENST00000628543; = p.I1677= on NM_152381.6) | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as COSV54684826; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+5271A>C | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV56138819; called by muse, mutect2, varscan2
- H2BP2 | n.1062-229G>A | Intron (SNP) | VAF 67/198 reads (34%) | called by muse, mutect2, varscan2
- H4C12 | c.-1C>T | 5'UTR (SNP) | VAF 44/120 reads (37%) | catalogued as rs373173429; called by muse, mutect2, varscan2
- KCNK1 | c.356-16601_356-16593del | Intron (DEL) | VAF 111/144 reads (77%) | called by mutect2, pindel, varscan2
- SERPINA3 | c.-30C>T | 5'UTR (SNP) | VAF 17/74 reads (23%) | catalogued as COSV101261770, COSV101261820; called by muse, mutect2, varscan2
- WASF4P | n.1350C>T | RNA (SNP) | VAF 50/62 reads (81%) | catalogued as rs781916463; called by muse, mutect2, varscan2
- ZRANB2 | c.771-763A>T | Intron (SNP) | VAF 89/236 reads (38%) | catalogued as COSV54671031; called by muse, mutect2, varscan2
